Somatic mutation profile of tumor specimen TCGA-A2-A0SU-01A (aliquot TCGA-A2-A0SU-01A-11D-A099-09) from TCGA case TCGA-A2-A0SU, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 66.3 years (24,219 days).
Specimen TCGA-A2-A0SU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c89269d6-0711-4f2c-a5d0-b8e32f51733c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A2-A0SU-10A (Blood Derived Normal), aliquot TCGA-A2-A0SU-10A-01D-A099-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/71bfdd95-3ce6-4b3e-a5c0-af9162d272e5

The open-access MAF lists 31 somatic variants for this specimen: 25 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 15, Silent 6, Frame Shift Del 4, In Frame Del 2, Nonsense Mutation 2, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA2 | c.9924C>G p.Y3308* | Nonsense Mutation (SNP) | VAF 28/70 reads (40%) | catalogued as rs4987049, CM065034, COSV99061404; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACACA | c.6497G>A p.R2166H | Missense Mutation (SNP) | VAF 39/208 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1567673018; called by muse, mutect2, varscan2
- ACLY | c.2996C>T p.P999L | Missense Mutation (SNP) | VAF 68/236 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV59862145; called by muse, mutect2, varscan2
- ACTG1 | c.1014_1015del p.W340Dfs*18 | Frame Shift Del (DEL) | VAF 10/68 reads (15%) | catalogued as COSV59510726; called by mutect2, pindel, varscan2
- ADGRE3 | c.47T>A p.L16H | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.552); catalogued as COSV99505805; called by muse, mutect2
- ALOXE3 | c.352+2T>G p.X118_splice | Splice Site (SNP) | VAF 31/74 reads (42%) | catalogued as COSV100502908; called by muse, mutect2, varscan2
- C19orf53 | c.206C>G p.A69G | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1215488436, COSV99684249; called by muse, mutect2, varscan2
- CACNA1A | c.5434G>A p.V1812I | Missense Mutation (SNP) | VAF 59/219 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100800907; called by muse, mutect2, varscan2
- CACNA1H | c.3758G>A p.R1253H | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs534632699, COSV61992486; called by muse, mutect2
- CEP131 | c.1132C>T p.Q378* | Nonsense Mutation (SNP) | VAF 33/68 reads (49%) | catalogued as COSV53953512; called by muse, mutect2, varscan2
- GATA3 | c.1221dup p.P408Afs*99 | Frame Shift Ins (INS) | VAF 27/134 reads (20%) | catalogued as COSV100650835, COSV100651341, COSV60515158, COSV60515274, COSV60515375, COSV60517941; called by mutect2, pindel, varscan2
- GCC1 | c.1790C>T p.T597I | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1380773692, COSV58462780; called by muse, mutect2, varscan2
- HAUS5 | c.995G>A p.R332H | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs199677903; called by muse, mutect2, varscan2
- MOCOS | c.1283C>T p.A428V | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV54344324; called by muse, mutect2, varscan2
- REG3A | c.406A>T p.N136Y | Missense Mutation (SNP) | VAF 39/145 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV59409821; called by muse, mutect2, varscan2
- RGS12 | c.753C>A p.S251R | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV60905984; called by muse, mutect2, varscan2
- SAMD9L | c.3230G>T p.R1077L | Missense Mutation (SNP) | VAF 8/143 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as COSV59080462, COSV59082718; called by muse, mutect2
- TAS2R5 | c.136C>G p.L46V | Missense Mutation (SNP) | VAF 58/260 reads (22%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.909); catalogued as rs759494239, COSV56095055; called by muse, mutect2, varscan2
- TRAPPC9 | c.2073T>G p.I691M | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV66901147; called by muse, mutect2, varscan2
- UBC | c.1255G>T p.D419Y | Missense Mutation (SNP) | VAF 34/280 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as COSV60059784; called by muse, mutect2, varscan2
- DENND11 | c.863_871del p.I288_G290del | In Frame Del (DEL) | VAF 27/147 reads (18%) | called by mutect2, pindel, varscan2
- GIMAP7 | c.102del p.F34Lfs*29 | Frame Shift Del (DEL) | VAF 4/40 reads (10%) | called by mutect2, pindel, varscan2
- IFT122 | c.1894del p.E632Kfs*23 (on ENST00000348417 / NM_052989.3; = p.E573Kfs*23 on NM_018262.4) | Frame Shift Del (DEL) | VAF 27/136 reads (20%) | called by mutect2, pindel, varscan2
- SLC38A10 | c.248_259del p.M83_E86del | In Frame Del (DEL) | VAF 8/38 reads (21%) | called by mutect2, pindel, varscan2
- TMEM213 | c.5_17del p.Q2_?6 | Frame Shift Del (DEL) | VAF 8/37 reads (22%) | called by mutect2, pindel, varscan2
- ADAMTS18 | c.3186C>T p.S1062= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as rs752883058, COSV51415829; called by muse, mutect2, varscan2
- ARFGEF3 | c.2229C>T p.L743= | Silent (SNP) | VAF 27/104 reads (26%) | catalogued as rs776381980, COSV52459223; called by muse, mutect2, varscan2
- FNDC7 | c.1032C>T p.G344= | Silent (SNP) | VAF 44/165 reads (27%) | catalogued as COSV54754502, COSV99601464; called by muse, mutect2, varscan2
- MOXD1 | c.1125C>T p.A375= | Silent (SNP) | VAF 24/82 reads (29%) | catalogued as rs749041512, COSV60945099; called by muse, mutect2, varscan2
- NCAN | c.2145G>A p.Q715= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV53052171; called by muse, mutect2, varscan2
- PNMT | c.315C>G p.V105= | Silent (SNP) | VAF 5/53 reads (9%) | catalogued as COSV54093198; called by muse, mutect2, varscan2
